Somatic mutation profile of tumor specimen TCGA-D3-A2JL-06A (aliquot TCGA-D3-A2JL-06A-11D-A196-08) from TCGA case TCGA-D3-A2JL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 49.6 years (18,118 days).
Specimen TCGA-D3-A2JL-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ff8aeaa-c664-4cd9-8e44-28420d1989ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2JL-10A (Blood Derived Normal), aliquot TCGA-D3-A2JL-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55092c8b-e431-481e-b3a2-11b3e715cb72

The open-access MAF lists 359 somatic variants for this specimen: 232 protein-altering or splice-affecting, 111 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 111, Nonsense Mutation 15, Splice Site 7, RNA 7, Intron 5, 3'UTR 2, Frame Shift Del 2, In Frame Del 1, 5'Flank 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by mutect2, varscan2
- NRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 37/159 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2681A>G p.D894G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59208556; called by muse, mutect2, varscan2
- ABCA12 | c.1181-1G>A p.X394_splice (on ENST00000272895 / NM_173076.3; = p.X76_splice on NM_015657.3) | Splice Site (SNP) | VAF 31/97 reads (32%) | catalogued as COSV55970075; called by muse, mutect2, varscan2
- ABCB8 | c.175C>T p.L59F (on ENST00000297504 / NM_001282291.2; = p.L42F on NM_007188.5) | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs755543729, COSV52508720; called by muse, mutect2, varscan2
- ABCC4 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs375104829; called by muse, mutect2, varscan2
- ABCC9 | c.2093-1G>A p.X698_splice | Splice Site (SNP) | VAF 47/157 reads (30%) | catalogued as COSV53981213; called by muse, varscan2
- ACAA1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as COSV57178174; called by muse, mutect2, varscan2
- ACTC1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); catalogued as rs868254384, COSV51760596; called by mutect2, varscan2
- ACTL6A | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV66999292; called by muse, mutect2, varscan2
- ACTR2 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV53202577; called by muse, mutect2, varscan2
- ADAMTS10 | c.629G>C p.R210P | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV54357772, COSV99547267; called by muse, mutect2, varscan2
- ADAMTS20 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101166363; called by mutect2, varscan2
- ADGRG4 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54953217, COSV54954732; called by muse, mutect2, varscan2
- AGBL1 | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759191613, COSV66848829; called by mutect2, varscan2
- AK7 | c.1835G>A p.G612D | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV50878018; called by muse, mutect2, varscan2
- AK7 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as rs759825760, COSV50869227; called by muse, varscan2
- AKAP13 | c.5623C>T p.R1875W (on ENST00000394518 / NM_007200.5; = p.R1879W on NM_006738.6) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.429); catalogued as rs760882035, COSV63465761; called by mutect2, varscan2
- AKT2 | c.821G>C p.R274P | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM041234, COSV60908915, COSV60909747; called by muse, mutect2, varscan2
- AMFR | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV51921616; called by mutect2, varscan2
- AMY2B | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141409903; called by muse, mutect2, varscan2
- AOC3 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772054920, COSV53828149; called by mutect2, varscan2
- ARHGAP39 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs781076391, COSV52770515; called by mutect2, varscan2
- ARHGAP6 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV61632970; called by mutect2, varscan2
- ARHGEF2 | c.521C>T p.S174F (on ENST00000361247 / NM_001162383.2; = p.S147F on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58114840; called by muse, varscan2
- ARMC4 | c.2220G>A p.W740* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as rs867142532, COSV59457421; called by muse, mutect2, varscan2
- ARMC6 | c.731G>A p.W244* (on ENST00000392336; = p.W219* on NM_033415.4) | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99523128; called by mutect2, varscan2
- ARMC6 | c.732G>A p.W244* (on ENST00000392336; = p.W219* on NM_033415.4) | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99523132; called by muse, mutect2, varscan2
- ARSD | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66973710; called by mutect2, varscan2
- ART4 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs1255305737, COSV57452921; called by muse, mutect2, varscan2
- ATP8A1 | c.3018C>T p.F1006= | Splice Region (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100046952; called by mutect2, varscan2
- AZU1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52142186; called by muse, mutect2, varscan2
- BCL11A | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 261/830 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59634818; called by muse, mutect2, varscan2
- BDP1 | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as rs1289026429, COSV62433352; called by mutect2, varscan2
- BTNL8 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 157/392 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs753356741, COSV51458261; called by muse, varscan2
- C1GALT1C1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV58974593, COSV58974689; called by muse, mutect2, varscan2
- C2orf16 | c.4796C>T p.S1599F | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV62677446; called by muse, mutect2, varscan2
- C6orf118 | c.149A>T p.K50I | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV57817607; called by muse, varscan2
- CDH10 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV52576110; called by muse, mutect2, varscan2
- CDH8 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs1419379407, COSV100179912, COSV54888050; called by mutect2, varscan2
- CFAP57 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV63016803; called by muse, varscan2
- CFHR4 | c.1682C>T p.S561L (on ENST00000367416 / NM_001201551.2; = p.S315L on NM_006684.5) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV52233675; called by mutect2, varscan2
- CHGB | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV66761410; called by muse, mutect2, varscan2
- CLUH | c.1132C>T p.R378* (on ENST00000435359; = p.R416* on NM_015229.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV70929724; called by mutect2, varscan2
- COL4A1 | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011168, COSV65429692; called by muse, mutect2, varscan2
- COL6A3 | c.392C>G p.T131S | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV55102199; called by muse, mutect2
- CPEB3 | c.1607A>G p.D536G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV56461063; called by muse, mutect2, varscan2
- CTIF | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV56489111; called by muse, mutect2, varscan2
- DCAF4 | c.30A>T p.R10S | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100611127; called by muse, varscan2
- DCAF4 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 56/180 reads (31%) | catalogued as COSV62320700; called by mutect2, varscan2
- DDX28 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV60106019; called by mutect2, varscan2
- DDX51 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs749051599, COSV57959456; called by muse, mutect2, varscan2
- DIDO1 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1161926156, COSV56629996; called by muse, mutect2, varscan2
- DIDO1 | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV99826651; called by muse, mutect2, varscan2
- DKK2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.135); catalogued as COSV53401421; called by mutect2, varscan2
- DNAH10 | c.5555C>T p.T1852I (on ENST00000409039; = p.T1791I on NM_207437.3) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.245); catalogued as rs1160030668, COSV68998829; called by muse, varscan2
- DNAH8 | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as rs553578959, COSV59469912; called by mutect2, varscan2
- DPH2 | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 96/333 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV52544537; called by muse, mutect2, varscan2
- DPP10 | c.2138G>A p.G713D | Missense Mutation (SNP) | VAF 90/301 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.148); catalogued as COSV59710182; called by muse, mutect2, varscan2
- DSC3 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64574524; called by muse, mutect2, varscan2
- DSCAM | c.5593G>A p.E1865K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs868479761, COSV68023424; called by mutect2, varscan2
- DTNBP1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.083); catalogued as COSV59042931; called by muse, mutect2, varscan2
- DUSP9 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV61438270; called by muse, mutect2, varscan2
- EDRF1 | c.2953T>A p.S985T (on ENST00000356792 / NM_001202438.2; = p.S951T on NM_015608.2) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.359); catalogued as COSV61765622; called by mutect2, varscan2
- EPAS1 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as COSV55389098; called by muse, mutect2, varscan2
- ESYT3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 53/312 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV56681374; called by muse, mutect2, varscan2
- EVC2 | c.3914T>A p.L1305* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as COSV60399494; called by muse, mutect2, varscan2
- EYA1 | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV58170134; called by muse, varscan2
- FAM171A1 | c.2468G>A p.R823K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.86); PolyPhen benign (0.012); catalogued as COSV65318592; called by muse, mutect2, varscan2
- FAM3B | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV63613640; called by muse, mutect2, varscan2
- FBXL18 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs185800545; called by muse, mutect2, varscan2
- FBXO32 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV54892243; called by muse, mutect2, varscan2
- FBXW9 | c.944C>T p.A315V (on ENST00000587955; = p.A295V on NM_032301.3) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as COSV100982052; called by muse, mutect2, varscan2
- FGD3 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as rs1467308537, COSV61599207; called by muse, mutect2, varscan2
- FLG | c.8338C>T p.Q2780* | Nonsense Mutation (SNP) | VAF 100/694 reads (14%) | catalogued as rs775264011, COSV64245882; called by muse, mutect2, varscan2
- FLG | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV64237476, COSV64246276; called by muse, mutect2, varscan2
- FLT1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs1351200892, COSV56737076; called by muse, mutect2, varscan2
- GALNT17 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs750663732, COSV100355269, COSV61167202; called by mutect2, varscan2
- GSTP1 | c.578T>C p.F193S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV66992741; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100736453; called by mutect2, varscan2
- GYS2 | c.1909C>T p.P637S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV53926994; called by mutect2, varscan2
- HDAC5 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52243524; called by muse, mutect2, varscan2
- HEATR6 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); catalogued as COSV51747819; called by muse, varscan2
- HIVEP2 | c.2939C>T p.S980F | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50036632; called by muse, varscan2
- IGLV1-51 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 96/180 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as rs758811706; called by muse, mutect2, varscan2
- IGSF1 | c.326G>A p.W109* | Nonsense Mutation (SNP) | VAF 46/123 reads (37%) | catalogued as COSV63839213; called by muse, mutect2, varscan2
- IKZF5 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as rs1157086424, COSV64397891; called by muse, mutect2, varscan2
- IQCC | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52210549; called by muse, mutect2, varscan2
- ISM2 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.117); catalogued as rs1366252054, COSV53636376; called by muse, mutect2, varscan2
- JSRP1 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV55553935; called by muse, varscan2
- KALRN | c.8032G>A p.E2678K (on ENST00000360013 / NM_001024660.4; = p.E981K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV52261951; called by muse, mutect2, varscan2
- KCNK10 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56649883; called by muse, mutect2, varscan2
- KCNQ5 | c.2711G>A p.R904K | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV59675510; called by muse, mutect2, varscan2
- KDR | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV55768529; called by muse, mutect2, varscan2
- KEL | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV62336913; called by muse, varscan2
- KIAA1210 | c.2818G>A p.D940N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs199658448, COSV68179033; called by mutect2, varscan2
- KIAA1549 | c.3842C>T p.A1281V | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54323580; called by muse, varscan2
- KIF27 | c.4166C>T p.S1389F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52830206; called by muse, mutect2, varscan2
- KRIT1 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV60669801; called by muse, mutect2
- KRT84 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs867590669, COSV57773071; called by muse, mutect2, varscan2
- LAMA2 | c.4270G>A p.G1424R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV70352806; called by muse, mutect2, varscan2
- LIPF | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53285660; called by muse, mutect2, varscan2
- LRP2 | c.10721C>A p.A3574D | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV99789708; called by muse, mutect2, varscan2
- LRRC46 | c.517T>C p.W173R | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.147); catalogued as COSV51637005; called by muse, mutect2, varscan2
- LRRC49 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs199883910, COSV53011514; called by mutect2, varscan2
- LRRK2 | c.4352G>A p.G1451D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54164382; called by mutect2, varscan2
- MAGED1 | c.313A>G p.N105D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.444); catalogued as rs782524377, COSV58516274; called by muse, mutect2, varscan2
- MAGEE2 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV64898261; called by muse, mutect2, varscan2
- MAPK15 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as rs537644016, COSV62029386; called by muse, mutect2, varscan2
- MFAP1 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as rs776902073, COSV51040371; called by mutect2, varscan2
- MIA2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54485433; called by mutect2, varscan2
- MORC1 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV51715216; called by muse, mutect2, varscan2
- MORC4 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV55245391; called by mutect2, varscan2
- MOV10L1 | c.3217-1G>A p.X1073_splice | Splice Site (SNP) | VAF 16/68 reads (24%) | catalogued as COSV99434656; called by muse, mutect2
- MOV10L1 | c.3217G>A p.V1073M | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs905296299, COSV99434657; called by muse, mutect2
- MS4A15 | c.505G>A p.D169N (on ENST00000405633 / NM_001098835.2; = p.D76N on NM_152717.3) | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV100558917; called by muse, mutect2, varscan2
- MTHFD1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53702671; called by muse, mutect2, varscan2
- MTOR | c.4922C>T p.S1641F | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772556623, COSV63875974; called by muse, mutect2, varscan2
- MUC6 | c.3829G>A p.A1277T | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV101424711; called by muse, mutect2, varscan2
- MXRA5 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV54244704; called by muse, mutect2, varscan2
- NAALAD2 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV58964413; called by muse, mutect2, varscan2
- NALCN | c.2344C>T p.L782F | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.415); catalogued as COSV51954776; called by muse, mutect2, varscan2
- NCAN | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.099); catalogued as COSV53055779; called by mutect2, varscan2
- NCAPH | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV53637827; called by muse, mutect2, varscan2
- NCKAP5 | c.4858G>A p.E1620K | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58433941; called by muse, varscan2
- NCSTN | c.844-1G>A p.X282_splice | Splice Site (SNP) | VAF 31/104 reads (30%) | catalogued as COSV54190428; called by muse, mutect2, varscan2
- NES | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63962285; called by muse, mutect2, varscan2
- NFATC4 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV51608416; called by muse, mutect2, varscan2
- NLGN3 | c.2144G>A p.G715E (on ENST00000358741 / NM_181303.2; = p.G695E on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100704959; called by muse, mutect2, varscan2
- NLRP7 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.471); catalogued as COSV60179182; called by muse, mutect2, varscan2
- NPEPL1 | c.485C>A p.P162Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV61940257; called by muse, mutect2, varscan2
- NPHS2 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62636161; called by muse, mutect2, varscan2
- NR4A2 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV59893478; called by muse, mutect2, varscan2
- NXF3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV67704701; called by mutect2, varscan2
- OGDHL | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65103923; called by muse, mutect2, varscan2
- OPALIN | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs775414162, COSV64520830; called by muse, mutect2, varscan2
- OPN4 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745384546, COSV54118286; called by muse, mutect2, varscan2
- OR1E1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV59459423; called by muse, mutect2, varscan2
- OR2T1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs769406328, COSV63541354; called by muse, mutect2, varscan2
- OR2T4 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267598505, COSV63544784; called by mutect2, varscan2
- OR7D4 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs140587334, COSV58071275; called by mutect2, varscan2
- OR8J3 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV56883156; called by muse, mutect2, varscan2
- PCDH17 | c.1414T>C p.F472L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV64977300; called by muse, mutect2, varscan2
- PCDHGB3 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54002947, COSV99538730; called by muse, varscan2
- PDE1A | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs747334904, COSV59513247; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV59014807; called by muse, mutect2, varscan2
- PIK3C2A | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.802); catalogued as COSV56405579; called by mutect2, varscan2
- PITPNM3 | c.352-1G>A p.X118_splice | Splice Site (SNP) | VAF 20/36 reads (56%) | catalogued as COSV52598530; called by muse, mutect2, varscan2
- PKHD1L1 | c.10446G>C p.W3482C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65739145, COSV65740271; called by muse, mutect2, varscan2
- PLEC | c.10906A>G p.N3636D (on ENST00000322810 / NM_201380.4; = p.N3526D on NM_000445.5) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV59675068; called by muse, mutect2, varscan2
- PLEKHA4 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV54365060; called by muse, mutect2, varscan2
- PLIN5 | c.1186G>C p.V396L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV101113622, COSV67850684; called by muse, mutect2, varscan2
- PPP2R2B | c.934G>A p.E312K (on ENST00000394409; = p.E378K on NM_181674.2) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV60773633; called by muse, mutect2, varscan2
- PRICKLE1 | c.2325A>C p.E775D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58209267; called by muse, varscan2
- PRKCZ | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV66070011; called by muse, mutect2, varscan2
- PSG5 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as rs1568371912, COSV61654901; called by muse, mutect2, varscan2
- PSMD2 | c.1846T>A p.C616S | Missense Mutation (SNP) | VAF 79/236 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV59530945; called by muse, mutect2, varscan2
- PTGFR | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as rs1259928177, COSV66115350; called by muse, varscan2
- PTPRB | c.4216G>A p.E1406K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV54249090, COSV99718457; called by muse, mutect2, varscan2
- PTPRS | c.4883G>A p.R1628H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1057017143, COSV53631329; called by muse, mutect2, varscan2
- RADIL | c.2692G>A p.D898N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101271568; called by muse, mutect2, varscan2
- RASSF9 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV63435273; called by muse, mutect2, varscan2
- RBM25 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV56201857; called by muse, mutect2, varscan2
- RBM46 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55979680, COSV55981235; called by muse, mutect2, varscan2
- RBM47 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs996457571, COSV55934709, COSV55941792; called by muse, mutect2, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by mutect2, varscan2
- RMI2 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56964380; called by muse, mutect2, varscan2
- RNPS1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV57044610; called by muse, varscan2
- RTL3 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs148985625, COSV58183919; called by mutect2, varscan2
- RXFP2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV53638880; called by muse, mutect2, varscan2
- SART1 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56713117; called by muse, varscan2
- SBNO1 | c.440C>T p.P147L (on ENST00000420886; = p.P146L on NM_018183.5) | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV57344395; called by muse, mutect2, varscan2
- SEPTIN9 | c.385C>T p.R129W (on ENST00000427177 / NM_001113491.2; = p.R111W on NM_006640.4) | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs201442609, COSV100218675; called by mutect2, varscan2
- SERINC3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV54857911; called by muse, mutect2, varscan2
- SGSM1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1345151399, COSV68509010; called by muse, mutect2, varscan2
- SHROOM2 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs771696352, COSV66605503, COSV66611773; called by mutect2, varscan2
- SIGLEC10 | c.350T>C p.F117S | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV59485272; called by muse, varscan2
- SLC12A6 | c.1493G>A p.G498D (on ENST00000354181 / NM_001365088.1; = p.G447D on NM_005135.2) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285975468, COSV51629369; called by muse, mutect2, varscan2
- SLC28A1 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1037805732, COSV54483325; called by muse, mutect2, varscan2
- SLC30A8 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV69974426; called by muse, mutect2, varscan2
- SLC45A4 | c.662C>T p.T221I (on ENST00000517878 / NM_001286646.2; = p.T170I on NM_001080431.2) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50236942; called by muse, mutect2, varscan2
- SLC6A13 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1206127608, COSV58259414; called by muse, mutect2, varscan2
- SLC6A20 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs267599839, COSV62070906; called by muse, varscan2
- SMOC1 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as COSV62762711; called by mutect2, varscan2
- SORCS3 | c.1802G>A p.W601* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100865499; called by mutect2, varscan2
- SORCS3 | c.1803G>A p.W601* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV63803538; called by mutect2, varscan2
- SOX21 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV65375487; called by muse, mutect2, varscan2
- SPAM1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56145111, COSV56146457; called by muse, mutect2, varscan2
- SPINK14 | c.47T>A p.I16K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV63659013; called by muse, mutect2, varscan2
- SQSTM1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV52974651; called by muse, mutect2, varscan2
- STYK1 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50014591; called by muse, mutect2, varscan2
- SULT1B1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV60208858; called by muse, mutect2, varscan2
- TACC2 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57756746; called by muse, mutect2, varscan2
- TAF8 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV65896803; called by muse, mutect2, varscan2
- TBC1D32 | c.2714C>T p.S905L | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1277762372, COSV51540805; called by mutect2, varscan2
- TBX2 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1266677991, COSV53600342; called by mutect2, varscan2
- TCHHL1 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.382); catalogued as COSV64286882; called by muse, mutect2, varscan2
- THEMIS | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as COSV100965272, COSV64071333; called by mutect2, varscan2
- THOC6 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as COSV50188038; called by mutect2, varscan2
- TLCD4 | c.305-1G>A p.X102_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as COSV64633191; called by muse, varscan2
- TMEM251 | c.269C>T p.S90F (on ENST00000415050 / NM_001098621.4; = p.S58F on NM_015676.3) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV52093199; called by muse, mutect2, varscan2
- TNRC18 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as rs1412400211, COSV68087838; called by muse, varscan2
- TNS4 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54187233, COSV54189069; called by muse, mutect2, varscan2
- TNXB | c.5077G>A p.G1693R (on ENST00000647633; = p.G1446R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); catalogued as COSV64485558; called by muse, mutect2, varscan2
- TONSL | c.3335C>A p.P1112H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as COSV68049021; called by mutect2, varscan2
- TP53I13 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV56196363; called by muse, mutect2, varscan2
- TTC3 | c.5571T>G p.C1857W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV61294396; called by muse, varscan2
- TTF2 | c.1139C>G p.T380R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65633338; called by muse, mutect2, varscan2
- TTLL6 | c.2660G>A p.G887E (on ENST00000393382 / NM_001130918.3; = p.G580E on NM_173623.3) | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.149); catalogued as COSV64978484; called by muse, mutect2, varscan2
- U2SURP | c.2563C>T p.Q855* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV67532582; called by mutect2, varscan2
- UBE2J2 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100231302; called by muse, varscan2
- ULK4 | c.1793G>C p.C598S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV57217974; called by muse, mutect2, varscan2
- USP29 | c.948A>C p.Q316H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV54145375; called by muse, mutect2, varscan2
- USP43 | c.3332C>T p.S1111F | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV53305659; called by muse, mutect2, varscan2
- USP8 | c.226A>T p.R76* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV56165832, COSV56167025; called by mutect2, varscan2
- WFDC2 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54151907; called by muse, varscan2
- ZC4H2 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.432); catalogued as COSV62005377; called by muse, mutect2, varscan2
- ZFHX4 | c.9007G>A p.E3003K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV51484031; called by muse, mutect2
- ZFHX4 | c.9073C>T p.H3025Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50480992; called by mutect2, varscan2
- ZFP42 | c.871A>G p.N291D | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58818559; called by muse, mutect2, varscan2
- ZNF470 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57970210; called by muse, mutect2, varscan2
- ZNF596 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as rs375874171; called by mutect2, varscan2
- ZNF610 | c.1238T>C p.L413S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1329405563, COSV58345991; called by muse, mutect2, varscan2
- ZNF683 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV62875309; called by muse, varscan2
- ZNF704 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59925655, COSV59926920; called by muse, mutect2, varscan2
- ZNF783 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV65186352; called by muse, mutect2, varscan2
- ZZEF1 | c.5632C>T p.P1878S | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1213114223, COSV67559417; called by muse, mutect2, varscan2
- ARHGAP10 | c.1109del p.K370Rfs*42 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- NCOA1 | c.4128_4130del p.L1377del | In Frame Del (DEL) | VAF 89/323 reads (28%) | called by mutect2, pindel, varscan2
- OR2G3 | c.706A>G p.K236E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB7 | c.364del p.W122Gfs*13 | Frame Shift Del (DEL) | VAF 35/110 reads (32%) | called by mutect2, pindel, varscan2
- RELCH | c.1881_1896+18del p.X627_splice | Splice Site (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- ABCC10 | c.1087C>T p.L363= (on ENST00000372530 / NM_001198934.2; = p.L320= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV55091631, COSV55092330; called by muse, mutect2, varscan2
- ACVRL1 | c.126G>A p.K42= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV66360724; called by muse, mutect2, varscan2
- ADAM18 | c.6C>T p.F2= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV55852139; called by muse, varscan2
- ANK1 | c.270G>A p.Q90= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV55890776; called by muse, mutect2, varscan2
- ATOH7 | c.381G>A p.A127= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV65447720; called by mutect2, varscan2
- BCAM | c.1020G>A p.E340= | Silent (SNP) | VAF 174/515 reads (34%) | catalogued as COSV54304189; called by muse, mutect2, varscan2
- BMERB1 | c.132G>A p.A44= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs199651851, COSV55510960; called by muse, mutect2, varscan2
- CASS4 | c.150T>C p.G50= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as rs1160174465, COSV64387812; called by muse, varscan2
- CDH6 | c.1017G>A p.K339= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99419440; called by muse, mutect2, varscan2
- CHAT | c.1344C>T p.I448= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs754253168, COSV60330129; called by mutect2, varscan2
- COL22A1 | c.1065G>A p.R355= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV57352232; called by muse, mutect2, varscan2
- CPT1C | c.249G>A p.L83= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV54917637, COSV54921330; called by mutect2, varscan2
- CPXM1 | c.1899C>T p.D633= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as COSV66046366; called by mutect2, varscan2
- CTPS2 | c.1186C>T p.L396= | Silent (SNP) | VAF 89/297 reads (30%) | catalogued as COSV63723635; called by muse, mutect2, varscan2
- DLX2 | c.519G>A p.K173= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV52232616; called by muse, mutect2, varscan2
- DMBT1 | c.2124G>A p.S708= | Silent (SNP) | VAF 158/464 reads (34%) | catalogued as rs780514508, COSV57554051; called by mutect2, varscan2
- DOCK11 | c.3228C>T p.H1076= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV52244878; called by mutect2, varscan2
- DUXA | c.486G>A p.R162= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV73729789; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2571C>T p.S857= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs751902275, COSV62569834; called by muse, mutect2, varscan2
- EPHB1 | c.1821C>T p.V607= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV67667781; called by muse, mutect2, varscan2
- ERN2 | c.2529G>A p.G843= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as COSV55623659; called by muse, mutect2, varscan2
- EXTL1 | c.1530C>T p.A510= | Silent (SNP) | VAF 85/248 reads (34%) | catalogued as rs1451960870, COSV100958518, COSV65333162; called by muse, mutect2, varscan2
- FAT4 | c.13755C>T p.I4585= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100629211, COSV58691432; called by mutect2, varscan2
- FBXW9 | c.945C>T p.A315= (on ENST00000587955; = p.A295= on NM_032301.3) | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as rs777373986, COSV66709749; called by mutect2, varscan2
- FCGBP | c.2712G>A p.R904= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, varscan2
- FIP1L1 | c.1381C>A p.R461= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1162524758, COSV60998782; called by muse, mutect2, varscan2
- FLG | c.2058G>A p.Q686= | Silent (SNP) | VAF 110/451 reads (24%) | catalogued as rs766139040, COSV64245884; called by muse, mutect2, varscan2
- GAS6 | c.1833C>A p.L611= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV59854226; called by muse, mutect2, varscan2
- GRIA2 | c.858T>A p.P286= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV52400682; called by muse, mutect2, varscan2
- GRIN2A | c.2985G>A p.T995= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs781646325, COSV58049901; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GRPEL1 | c.336G>A p.L112= | Silent (SNP) | VAF 54/190 reads (28%) | catalogued as COSV53828106; called by muse, mutect2, varscan2
- GTPBP2 | c.954C>T p.I318= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs989940256, COSV61077082; called by mutect2, varscan2
- GYS2 | c.852T>C p.V284= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs774191079, COSV53927002; called by muse, mutect2, varscan2
- HCN4 | c.3324C>T p.S1108= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV56086126; called by muse, mutect2
- HEATR1 | c.5331C>T p.P1777= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV63982517, COSV63982837; called by muse, mutect2, varscan2
- HGFAC | c.1377C>T p.S459= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as rs370377470; called by muse, varscan2
- HRH1 | c.747G>A p.K249= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV67955815; called by muse, mutect2, varscan2
- HSPA1L | c.651G>A p.G217= | Silent (SNP) | VAF 94/630 reads (15%) | catalogued as COSV65149367; called by muse, mutect2, varscan2
- KCNH5 | c.297G>A p.K99= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100528559, COSV59770942; called by muse, mutect2, varscan2
- KIF24 | c.3144C>T p.L1048= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as rs1563932003, COSV52660957; called by mutect2, varscan2
- KLHL13 | c.1548C>T p.I516= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV53251415; called by muse, mutect2, varscan2
- KRT20 | c.867G>A p.L289= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as COSV51425756; called by mutect2, varscan2
- KRT34 | c.666G>A p.V222= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV67450425; called by muse, varscan2
- KRT79 | c.1356C>T p.S452= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1392147616, COSV57941690; called by mutect2, varscan2
- LMTK2 | c.2979C>T p.S993= | Silent (SNP) | VAF 70/204 reads (34%) | catalogued as COSV52001326; called by muse, mutect2, varscan2
- LTBP2 | c.111G>A p.R37= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV56211838; called by muse, varscan2
- MAGEC1 | c.1467C>T p.S489= | Silent (SNP) | VAF 64/222 reads (29%) | catalogued as rs769638180, COSV53578519; called by muse, mutect2, varscan2
- METRNL | c.672C>T p.A224= | Silent (SNP) | VAF 94/185 reads (51%) | catalogued as COSV60761582; called by muse, mutect2, varscan2
- MS4A15 | c.504G>A p.V168= (on ENST00000405633 / NM_001098835.2; = p.V75= on NM_152717.3) | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs1307936186, COSV100558916; called by mutect2, varscan2
- MUC16 | c.13461C>T p.T4487= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs189361076, COSV67482448; called by muse, varscan2
- MUC6 | c.3828G>A p.T1276= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as rs367910509; called by mutect2, varscan2
- NAP1L2 | c.63G>A p.Q21= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as COSV65172885; called by muse, mutect2, varscan2
- NCR3 | c.87C>T p.T29= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV53002231; called by muse, mutect2, varscan2
- NLGN3 | c.2145G>A p.G715= (on ENST00000358741 / NM_181303.2; = p.G695= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1444036815, COSV100704960; called by muse, mutect2, varscan2
- NLRP11 | c.312C>T p.F104= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV64088401; called by mutect2, varscan2
- NR4A2 | c.1251C>T p.I417= | Silent (SNP) | VAF 62/230 reads (27%) | catalogued as COSV59895002; called by muse, varscan2
- OCRL | c.294C>T p.I98= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV63981544; called by muse, varscan2
- OFD1 | c.360T>C p.T120= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as rs199934720, COSV60797811; called by muse, mutect2, varscan2
- OR10H1 | c.213C>T p.I71= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV58472532; called by muse, mutect2, varscan2
- OR2Z1 | c.87C>T p.S29= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV60693040, COSV60693520; called by muse, mutect2, varscan2
- OR4K5 | c.768C>T p.F256= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs865910370, COSV60002532; called by mutect2, varscan2
- OR51I2 | c.822C>T p.V274= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV58299724; called by muse, mutect2, varscan2
- PCDH10 | c.1563G>A p.E521= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs769667444, COSV52100682; called by muse, mutect2, varscan2
- PCDHA13 | c.270C>T p.I90= | Silent (SNP) | VAF 83/243 reads (34%) | catalogued as rs782086663, COSV56477733; called by muse, mutect2, varscan2
- PLB1 | c.4299C>T p.I1433= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs191637109, COSV59821148; called by mutect2, varscan2
- PLEC | c.8596C>T p.L2866= (on ENST00000322810 / NM_201380.4; = p.L2756= on NM_000445.5) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs376462203, COSV100511541; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEC | c.8595C>T p.I2865= (on ENST00000322810 / NM_201380.4; = p.I2755= on NM_000445.5) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100517251; called by muse, mutect2, varscan2
- PLIN4 | c.1935C>T p.I645= (on ENST00000301286; = p.I660= on NM_001367868.2) | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as rs759029294, COSV56696237; called by mutect2, varscan2
- PLIN5 | c.1185G>A p.L395= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV101113624; called by mutect2, varscan2
- PLXND1 | c.2664C>T p.C888= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV60717492; called by mutect2, varscan2
- PPP1R16B | c.1560G>A p.L520= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV55381906; called by mutect2, varscan2
- PPP1R26 | c.240C>T p.D80= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs781644488, COSV63358070; called by mutect2, varscan2
- PRR12 | c.2277C>T p.F759= (on ENST00000615927; = p.F1580= on NM_020719.3) | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs761790223, COSV69817859; called by mutect2, varscan2
- RADIL | c.2691G>A p.T897= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs776787702, COSV101271570; called by mutect2, varscan2
- RAI2 | c.666C>T p.S222= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV58965734; called by muse, mutect2, varscan2
- RANGAP1 | c.396C>T p.F132= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs754622496, COSV62362651; called by mutect2, varscan2
- RBBP6 | c.3753C>T p.V1251= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV60507660; called by mutect2, varscan2
- RCE1 | c.822G>A p.A274= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs139646297; called by mutect2, varscan2
- REXO1 | c.1341G>A p.G447= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1255102050, COSV50085773; called by mutect2, varscan2
- RIPOR3 | c.933G>A p.E311= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV50397556; called by muse, mutect2, varscan2
- RSF1 | c.1404G>A p.K468= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV57843876; called by muse, mutect2, varscan2
- RUBCNL | c.1941C>T p.I647= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV59792493; called by mutect2, varscan2
- SCN4A | c.4272C>T p.V1424= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV71128318; called by mutect2, varscan2
- SCN9A | c.513C>T p.I171= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV57601600; called by muse, mutect2, varscan2
- SEPTIN9 | c.384C>T p.S128= (on ENST00000427177 / NM_001113491.2; = p.S110= on NM_006640.4) | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as COSV100217463, COSV100218436; called by muse, mutect2, varscan2
- SLC12A7 | c.1263C>T p.T421= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs113279957, COSV53760844; called by muse, mutect2, varscan2
- SLC13A2 | c.759C>A p.L253= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV58997405; called by mutect2, varscan2
- SLC41A1 | c.321C>T p.L107= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs761004479, COSV65651107; called by muse, mutect2, varscan2
- SLC45A4 | c.663C>T p.T221= (on ENST00000517878 / NM_001286646.2; = p.T170= on NM_001080431.2) | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs756093271, COSV50134543; called by mutect2, varscan2
- SNTG2 | c.418C>T p.L140= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as COSV57999091; called by muse, mutect2, varscan2
- SPATA32 | c.777C>T p.P259= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV59304614; called by muse, varscan2
- SPINK14 | c.45G>A p.L15= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV63659001, COSV63659078; called by mutect2, varscan2
- SPOP | c.771C>T p.F257= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV61655175; called by mutect2, varscan2
- SPTBN5 | c.9894C>T p.T3298= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV58025646; called by muse, mutect2, varscan2
- SRCIN1 | c.2412G>A p.G804= (on ENST00000621492; = p.G770= on NM_025248.3) | Silent (SNP) | VAF 56/95 reads (59%) | catalogued as rs982835862; called by muse, mutect2, varscan2
- TOGARAM2 | c.2508C>T p.L836= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV65423112; called by muse, mutect2, varscan2
- TOM1L2 | c.282C>T p.F94= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV58884954; called by mutect2, varscan2
- TRAV12-2 | c.336G>A p.V112= | Silent (SNP) | VAF 49/179 reads (27%) | called by muse, mutect2, varscan2
- TSBP1 | c.1426C>T p.L476= (on ENST00000617061; = p.L481= on NM_006781.5) | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs1215693549, COSV66660382; called by muse, mutect2, varscan2
- TSHZ2 | c.2319G>A p.K773= | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as COSV61589086; called by muse, mutect2, varscan2
- TTLL4 | c.2730C>T p.S910= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV51438470; called by muse, mutect2, varscan2
- UBE2J2 | c.108C>T p.P36= | Silent (SNP) | VAF 79/264 reads (30%) | catalogued as COSV100231301; called by muse, varscan2
- UBR2 | c.1263C>T p.F421= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV65748666, COSV65751791; called by muse, mutect2, varscan2
- UPK3B | c.843C>T p.P281= (on ENST00000257632; = p.P253L on NM_001347684.2) | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV57537031; called by muse, mutect2, varscan2
- WARS2 | c.1020A>G p.A340= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as COSV52478066, COSV52481416; called by muse, mutect2, varscan2
- WDR3 | c.2574C>T p.F858= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV60464759; called by muse, mutect2, varscan2
- XKR4 | c.1725G>A p.V575= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV59329702; called by mutect2, varscan2
- ZDBF2 | c.5043G>A p.Q1681= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV65628767; called by muse, mutect2, varscan2
- ZNF184 | c.2097C>T p.N699= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs376889374; called by muse, mutect2, varscan2
- ZNF341 | c.1698C>T p.F566= (on ENST00000375200 / NM_001282935.1; = p.F559= on NM_032819.4) | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as rs866135172, COSV61006849, COSV61010361; called by muse, varscan2
- ZNF480 | c.169T>C p.L57= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV57997632; called by muse, mutect2, varscan2
- AK2 | c.*80C>T | 3'UTR (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100710038; called by muse, varscan2
- AK2 | c.*79C>T | 3'UTR (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100710039; called by muse, varscan2
- C8orf86 | n.575_576dup | RNA (INS) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- CXCL12 | c.266+2629G>A | Intron (SNP) | VAF 62/485 reads (13%) | catalogued as rs267602491, COSV100639012; called by muse, varscan2
- LGR6 | c.212+9617G>A | Intron (SNP) | VAF 31/97 reads (32%) | catalogued as rs138365182; called by muse, mutect2, varscan2
- MIR329-2 | n.50G>A | RNA (SNP) | VAF 98/237 reads (41%) | catalogued as rs775070459; called by muse, mutect2, varscan2
- OBSCN | c.11659+4456C>T | Intron (SNP) | VAF 44/147 reads (30%) | catalogued as rs1314110429, COSV99482347; called by muse, mutect2, varscan2
- PNO1 | chr2:68157649 G>A | 5'Flank (SNP) | VAF 30/77 reads (39%) | catalogued as rs1443939229; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792059 C>T | 3'Flank (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- SLC17A3 | c.304-151C>T | Intron (SNP) | VAF 9/19 reads (47%) | catalogued as COSV57759513; called by muse, mutect2, varscan2
- SNORD116-25 | n.5C>T | RNA (SNP) | VAF 6/32 reads (19%) | catalogued as rs202200546; called by mutect2, varscan2
- SNORD116-4 | n.34C>T | RNA (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- SPATA8 | n.307C>A | RNA (SNP) | VAF 27/63 reads (43%) | catalogued as COSV60705360; called by muse, mutect2, varscan2
- SPATA8 | n.886C>T | RNA (SNP) | VAF 38/144 reads (26%) | catalogued as COSV60703926; called by muse, varscan2
- TUBB7P | n.220G>A | RNA (SNP) | VAF 36/140 reads (26%) | called by muse, varscan2
- ZNF783 | c.802+3078C>T | Intron (SNP) | VAF 15/78 reads (19%) | catalogued as rs746201321, COSV65186358; called by muse, mutect2, varscan2
